Somatic mutation profile of tumor specimen TARGET-30-PARYEH-01A (aliquot TARGET-30-PARYEH-01A-01D) from TARGET case TARGET-30-PARYEH, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 0.6 years (201 days).
Specimen TARGET-30-PARYEH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53ed9351-b814-4def-8996-24bf67bb8110.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARYEH-10A (Blood Derived Normal), aliquot TARGET-30-PARYEH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1276b43-0f43-4d7d-b925-d5c37351dd58

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDAC9 | c.2184A>C p.S728= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV67787910; called by muse, mutect2, varscan2
- NONO | c.309C>A p.V103= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
